Somatic mutation profile of tumor specimen TCGA-UT-A88C-01B (aliquot TCGA-UT-A88C-01B-11D-A39R-32) from TCGA case TCGA-UT-A88C, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 63.0 years (23,002 days).
Specimen TCGA-UT-A88C-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 032d50a4-b8eb-4204-82d9-03822b73ed6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UT-A88C-10A (Blood Derived Normal), aliquot TCGA-UT-A88C-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b901c9-3959-4d92-a0d9-52063e5dee07

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 13, Silent 9, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUH | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.294); catalogued as COSV57861624; called by muse, mutect2, varscan2
- BAP1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as CM1515070, COSV56230698; called by muse, mutect2, varscan2
- COG8 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201787629; called by muse, mutect2, varscan2
- DHX16 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs765508826, COSV100905277; called by muse, mutect2, varscan2
- G2E3 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52843384; called by muse, mutect2, varscan2
- JHY | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99914060; called by muse, mutect2, varscan2
- SETD2 | c.3752C>A p.S1251* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV57435811, COSV57439483; called by muse, mutect2, varscan2
- SPOPL | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.345); catalogued as rs746850288; called by muse, mutect2, varscan2
- ANKRD55 | c.1695C>A p.N565K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATP13A1 | c.3476A>G p.Q1159R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CUL5 | c.624T>G p.D208E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAVCR1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- HSPA13 | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAF | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.334); called by muse, mutect2
- USP28 | c.2261C>A p.A754D | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2
- ZNF333 | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHNAK2 | c.10005G>A p.A3335= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs377637192; called by muse, mutect2, varscan2
- ARHGAP25 | c.1719G>A p.E573= (on ENST00000409202 / NM_001007231.3; = p.E565= on NM_014882.3) | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- CNOT10 | c.564A>G p.G188= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- IQUB | c.2313C>T p.I771= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV61236947; called by muse, mutect2, varscan2
- KIAA1549 | c.1914C>T p.I638= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- NOS3 | c.2409G>A p.P803= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs746131743; called by muse, mutect2, varscan2
- PRAME | c.678C>A p.I226= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs1294632054; called by muse, mutect2, varscan2
- SERPINB13 | c.717C>T p.N239= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- SLC20A1 | c.1011C>T p.D337= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
